Gene-level copy-number profile of tumor specimen HCM-BROD-0485-C15-06A from HCMI case HCM-BROD-0485-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 46.5 years (16,967 days).
Specimen HCM-BROD-0485-C15-06A: Sample type: Human Tumor Original Cells; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Human Original Cells; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e226a641-ef9d-494a-96e2-c0b38c11dcb6.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0485-C15-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,743 have no estimate.
https://portal.gdc.cancer.gov/files/2d1a080e-0b54-46f4-8bee-953f4aab231c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 21; copy number 1: 12,823; copy number 2: 30,727; copy number 3: 13,046; copy number 4: 1,237; copy number 5: 727; copy number 6: 131; copy number 7: 41; copy number 8: 27; copy number 9: 49; copy number 10: 3; copy number 15: 5; copy number 24: 10; copy number 63: 11; copy number 91: 22.

Homozygous deletions (total copy number 0; autosomes only): 21 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:161,347,417–163,315,492, 10 genes (within-gene range 0–2): PRKN, AL132982.1, AL138716.1, KRT8P44, PACRG, AL590286.1, AL590286.2, PACRG-AS2, AL137182.1, PACRG-AS3.
- chr9:12,134–89,850, 7 genes: DDX11L5, WASHC1, MIR1302-9HG, MIR1302-9, FAM138C, AL449043.2, PGM5P3-AS1.
- chr9:9,442,060–9,803,784, 2 genes (within-gene range 0–1): RN7SL5P, AL513422.1.
- chr20:50,888,916–50,931,437, 2 genes (within-gene range 0–1): ADNP, PSMD10P1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,026 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:23,801,885–24,112,135, 13 genes, copy number 5: HMGCL, FUCA1, CNR2, BTBD6P1, AL590609.2, MIR378F, H3P1, PNRC2, SRSF10, AL590609.1, AL591178.1, MYOM3, MYOM3-AS1.
- chr2:19,826,249–20,861,661, 32 genes, copy number 5–24: CISD1P1, LINC00954, TTC32, AC013400.1, WDR35, AC079145.1, MATN3, LAPTM4A, LAPTM4A-DT, AC098828.1, RPS16P2, RN7SL140P, RNU6-961P, SDC1, DRG1P1, RNU7-113P, PUM2, SLC7A15P, RNA5SP86, RHOB, AC023137.1, Y_RNA, AC012065.1, NDUFAF2P1, HS1BP3, AC012065.2, HS1BP3-IT1, RPS25P3, GDF7, AC012065.3, LDAH, LINC02850.
- chr3:162,486,541–163,479,500, 7 genes, copy number 5: TOMM22P6, AC128716.1, AC128685.1, LINC01192, RPS6P4, AC079910.1, RNU7-82P.
- chr3:167,392,796–167,479,004, 2 genes, copy number 5 (within-gene range 4–5): LINC01327, SERPINI2.
- chr3:168,858,659–174,286,644, 90 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr3:174,302,944–179,789,401, 71 genes, copy number 5–6 (within-gene range 5–7) (broad region; genes not listed).
- chr3:193,398,967–194,260,720, 20 genes, copy number 5: ATP13A4, ATP13A4-AS1, AC048351.1, OPA1, OPA1-AS1, Y_RNA, RN7SL447P, AC069421.1, LINC02038, LINC02026, AC024559.1, DPPA2P3, LINC02028, AC024559.2, AC080129.1, AC080129.2, HES1, RN7SL215P, LINC02036, LINC02037.
- chr3:196,867,856–198,123,232, 42 genes, copy number 5–7: SENP5, AC016949.1, NCBP2, NCBP2-AS1, NCBP2AS2, PIGZ, RPSAP69, MELTF, MELTF-AS1, DLG1, MIR4797, DLG1-AS1, AC128709.2, AC128709.1, AC128709.3, LINC02012, BDH1, AC132008.2, AC132008.1, AC024560.2, AC024560.3, AC024560.1, AC024560.5, RUBCN, MIR922, FYTTD1, AC055764.2, LRCH3, AC055764.1, AC144530.1, IQCG, RNU6-858P, RPL35A, LMLN, RNU6-621P, AC135893.1, LMLN-AS1, ANKRD18DP, RNU6-821P, FRG2FP, TUBB8P8, AC073135.1.
- chr7:141,551,278–141,841,487, 17 genes, copy number 5 (within-gene range 3–5): AGK, AC004918.1, DENND11, AC004918.3, WEE2-AS1, WEE2, RNU1-82P, SSBP1, TAS2R3, TAS2R4, TAS2R6P, TAS2R5, MTCO1P55, MTND2P5, MTND1P3, MYL6P4, PRSS37.
- chr8:12,104,389–12,115,516, 1 gene, copy number 7: ZNF705D.
- chr8:118,189,455–145,066,685, 472 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr12:20,361,732–25,814,171, 82 genes, copy number 9–91 (broad region; genes not listed).
- chr18:57,435,374–58,986,480, 38 genes, copy number 5–15 (within-gene range 4–15): ONECUT2, FECH, AC100847.1, NARS1, AC027097.1, AC027097.2, ATP8B1, RNU6-742P, RSL24D1P11, LINC01897, HMGN1P30, NEDD4L, AC107896.1, AC090236.2, AC090236.1, AC105105.2, MIR122HG, MIR122, MIR3591, AC105105.4, ALPK2, AC105105.3, AC105105.1, AC104971.2, SNORA108, RPL9P31, AC104971.3, AC104971.1, MALT1, AC104365.1, MRPL37P1, AC104365.3, AC104365.2, RNU6-219P, LINC01926, U8, ZNF532, RNU2-69P.
- chr19:14,840,466–16,690,023, 112 genes, copy number 5–8 (broad region; genes not listed).
- chr22:28,992,721–29,581,327, 27 genes, copy number 5 (within-gene range 3–5): ZNRF3-IT1, ZNRF3-AS1, C22orf31, KREMEN1, AL021393.1, RNU6-810P, RNU6-1219P, EMID1, RHBDD3, AL031186.1, EWSR1, GAS2L1, RASL10A, AC002059.1, AP1B1, AC002059.2, SNORD125, AC002059.3, AC000041.1, RFPL4AP6, RFPL1S, RFPL1, NEFH, AC000035.1, THOC5, AC005529.1, NIPSNAP1.

Autosomal genes at a single copy (total copy number 1): 9,994. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
